Somatic mutation profile of tumor specimen TCGA-12-0692-01A (aliquot TCGA-12-0692-01A-01W-0348-08) from TCGA case TCGA-12-0692, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 75.3 years (27,519 days).
Specimen TCGA-12-0692-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9095a8e7-7abf-40a0-9608-ffe2d80c532d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-0692-10A (Blood Derived Normal), aliquot TCGA-12-0692-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cbb82ca3-8ba5-4d07-b99f-218ab36ac16f

The open-access MAF lists 90 somatic variants for this specimen: 69 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 20, Nonsense Mutation 5, Frame Shift Del 3, Splice Site 2, Frame Shift Ins 2, Splice Region 1, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.1175T>G p.L392W | Missense Mutation (SNP) | VAF 80/960 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55964974; called by muse, mutect2
- ABCC8 | c.4522A>C p.T1508P | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs80075294; called by muse, mutect2
- ABCC9 | c.4151C>A p.T1384K | Missense Mutation (SNP) | VAF 294/452 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV53971376; called by muse, mutect2, varscan2
- ADAM29 | c.1537G>A p.A513T | Missense Mutation (SNP) | VAF 1261/1995 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760244397, COSV63663582; called by muse, mutect2, varscan2
- AFM | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 84/151 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.174); catalogued as rs372542885; called by muse, mutect2
- ATP10B | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 166/367 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376023056; called by muse, mutect2, varscan2
- AURKAIP1 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745722308, COSV57938568; called by muse, mutect2, varscan2
- BARD1 | c.1837del p.A613Qfs*6 | Frame Shift Del (DEL) | VAF 61/276 reads (22%) | catalogued as COSV53613149; called by mutect2, pindel, varscan2
- CCAR1 | c.246+1G>C p.X82_splice | Splice Site (SNP) | VAF 28/37 reads (76%) | catalogued as COSV56269821; called by muse, mutect2, varscan2
- CCNO | c.419T>C p.L140P | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57004747; called by muse, mutect2
- CCT2 | c.1396A>G p.R466G | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1243536298; called by muse, mutect2
- CD109 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 196/397 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs1213149278, COSV54649392; called by muse, mutect2, varscan2
- CENPS-CORT | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 80/1194 reads (7%) | catalogued as COSV58364033; called by muse, mutect2
- CHEK1 | c.1294G>T p.E432* | Nonsense Mutation (SNP) | VAF 27/764 reads (4%) | catalogued as COSV54022744; called by muse, mutect2
- CRTAC1 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 189/198 reads (95%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.86); catalogued as rs149424033; called by muse, mutect2, varscan2
- CYP2D6 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as rs779730092, COSV62243013; called by muse, mutect2, varscan2
- DEFB114 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs146020038, COSV59037894; called by muse, mutect2, varscan2
- DMD | c.4450C>T p.H1484Y | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as CD165356; called by muse, mutect2
- DNM1 | c.1228G>T p.E410* | Nonsense Mutation (SNP) | VAF 8/100 reads (8%) | catalogued as COSV57856680; called by muse, mutect2
- EDDM3B | c.115T>G p.L39V | Missense Mutation (SNP) | VAF 271/476 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as rs201861023, COSV58746982; called by muse, mutect2, varscan2
- ENTHD1 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 415/723 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1463294299, COSV57318141, COSV57320234, COSV57323027; called by muse, mutect2, varscan2
- FLT3 | c.2316A>T p.K772N | Missense Mutation (SNP) | VAF 214/450 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as COSV54053920; called by mutect2, varscan2
- GON4L | c.848A>C p.Q283P | Missense Mutation (SNP) | VAF 338/700 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV55193408; called by muse, mutect2, varscan2
- GRID2 | c.1278T>G p.N426K | Missense Mutation (SNP) | VAF 24/346 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV56205481; called by muse, mutect2
- H3-4 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.8); catalogued as COSV64210419; called by muse, mutect2, varscan2
- IGF2BP1 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 64/111 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.676); catalogued as rs1364176184, COSV51731262; called by muse, mutect2, varscan2
- ITGAD | c.2669G>T p.R890M | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV66757977; called by muse, mutect2
- ITGAE | c.2098G>A p.V700I | Missense Mutation (SNP) | VAF 89/126 reads (71%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs967609574, COSV53993808; called by muse, mutect2, varscan2
- KANSL1 | c.1831G>A p.V611I | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs202150313; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2
- KIDINS220 | c.952G>T p.V318L | Missense Mutation (SNP) | VAF 22/583 reads (4%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.863); catalogued as rs1328089029; called by muse, mutect2
- MSL2 | c.1632T>A p.S544R | Missense Mutation (SNP) | VAF 91/182 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.29); catalogued as COSV53863808; called by muse, mutect2, varscan2
- NCOR1 | c.3943C>A p.P1315T | Missense Mutation (SNP) | VAF 28/444 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV51961805, COSV99063274; called by muse, mutect2
- OR1I1 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs372952340; called by muse, mutect2, varscan2
- OR51F1 | c.460G>T p.G154C | Missense Mutation (SNP) | VAF 22/291 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1286300919, COSV58579728, COSV58580090; called by muse, mutect2
- PPP6R3 | c.552+2T>G p.X184_splice | Splice Site (SNP) | VAF 145/419 reads (35%) | catalogued as COSV55726535; called by muse, mutect2, varscan2
- PPRC1 | c.4382dup p.H1462Tfs*10 | Frame Shift Ins (INS) | VAF 12/78 reads (15%) | catalogued as rs772864639; called by mutect2, varscan2
- SATL1 | c.815C>T p.P272L (on ENST00000395409; = p.P459L on NM_001012980.2) | Missense Mutation (SNP) | VAF 123/274 reads (45%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.991); catalogued as COSV100260952, COSV60576680; called by muse, mutect2, varscan2
- SMURF1 | c.1382G>A p.G461E | Missense Mutation (SNP) | VAF 44/718 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV63159512; called by muse, mutect2
- STAG2 | c.446del p.T149Mfs*34 | Frame Shift Del (DEL) | VAF 62/126 reads (49%) | catalogued as COSV54362445; called by mutect2, pindel*, varscan2
- STK31 | c.2182C>T p.R728* | Nonsense Mutation (SNP) | VAF 287/824 reads (35%) | catalogued as rs767028140, COSV63453851; called by muse, mutect2, varscan2
- STK35 | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs746321390, COSV55690545; called by muse, mutect2, varscan2
- TAF1 | c.1736G>A p.R579Q (on ENST00000373790 / NM_138923.4; = p.R600Q on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV99334068; called by muse, mutect2, varscan2
- TBL1X | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs200562052, COSV54280026; called by muse, mutect2
- TEK | c.3007C>T p.R1003C | Missense Mutation (SNP) | VAF 95/360 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772600804, COSV66228950; called by muse, mutect2, varscan2
- USP22 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1271984969, COSV54949346; called by muse, mutect2
- WNT2 | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as rs371599061, COSV99038559; called by muse, mutect2
- XIRP1 | c.5006C>A p.S1669Y | Missense Mutation (SNP) | VAF 68/238 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61138480; called by muse, mutect2, varscan2
- ZBTB33 | c.1048G>A p.V350I | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.969); catalogued as rs1231502325, COSV58533933; called by muse, mutect2, varscan2
- ZNF560 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV56867859; called by muse, mutect2, varscan2
- ZNF701 | c.329T>G p.L110R (on ENST00000301093; = p.L44R on NM_018260.3) | Missense Mutation (SNP) | VAF 54/490 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV56525196; called by muse, varscan2
- ARHGAP17 | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, varscan2
- BRD2 | c.1603G>T p.A535S | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.091); called by muse, mutect2
- CANX | c.154C>A p.P52T | Missense Mutation (SNP) | VAF 114/811 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTN5 | c.2917+1_2917+2dup | Frame Shift Ins (INS) | VAF 248/355 reads (70%) | called by mutect2, varscan2
- DUS3L | c.900G>C p.R300= | Splice Region (SNP) | VAF 14/32 reads (44%) | called by muse, varscan2
- FAM120C | c.2543G>T p.C848F | Missense Mutation (SNP) | VAF 59/275 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBLN5 | c.1266G>C p.M422I | Missense Mutation (SNP) | VAF 112/388 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by mutect2, varscan2
- FRMPD4 | c.3580C>T p.H1194Y | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- IPO5 | c.916C>A p.P306T | Missense Mutation (SNP) | VAF 25/245 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.838); called by muse, mutect2
- MOB3B | c.56G>T p.R19M | Missense Mutation (SNP) | VAF 179/1030 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, varscan2
- NBPF15 | c.1721G>A p.R574K | Missense Mutation (SNP) | VAF 236/755 reads (31%) | SIFT tolerated (1); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- NCSTN | c.1646G>T p.G549V | Missense Mutation (SNP) | VAF 70/1262 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.01); called by muse, mutect2
- SAMD9 | c.362A>G p.D121G | Missense Mutation (SNP) | VAF 48/448 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SIGLEC1 | c.5063C>A p.T1688N | Missense Mutation (SNP) | VAF 70/971 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- SRSF11 | c.764C>A p.S255Y | Missense Mutation (SNP) | VAF 22/428 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- TRMT6 | c.332_333del p.I111Kfs*9 | Frame Shift Del (DEL) | VAF 25/187 reads (13%) | called by mutect2, pindel, varscan2
- TTN | c.84529C>T p.Q28177* (on ENST00000591111; = p.Q20753* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- WFDC11 | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 32/1154 reads (3%) | SIFT tolerated (0.76); PolyPhen benign (0.09); called by muse, mutect2
- ZNF674 | c.756_758dup p.Y252_E253insD | In Frame Ins (INS) | VAF 7/28 reads (25%) | called by pindel, varscan2
- BRAP | c.1407G>T p.V469= | Silent (SNP) | VAF 18/408 reads (4%) | called by muse, mutect2
- BRAT1 | c.51A>G p.V17= | Silent (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- CEP164 | c.3357G>A p.Q1119= | Silent (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- DPF2 | c.324G>A p.K108= | Silent (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- DRC7 | c.1350C>A p.A450= | Silent (SNP) | VAF 6/33 reads (18%) | called by mutect2, varscan2
- FAM111B | c.549C>T p.C183= | Silent (SNP) | VAF 13/312 reads (4%) | called by muse, mutect2
- GSDMB | c.225T>C p.S75= | Silent (SNP) | VAF 20/218 reads (9%) | called by muse, mutect2
- INPP5D | c.267A>G p.E89= | Silent (SNP) | VAF 10/31 reads (32%) | called by mutect2, varscan2
- NLRP4 | c.2673G>A p.T891= | Silent (SNP) | VAF 209/368 reads (57%) | catalogued as rs201059514; called by muse, mutect2, varscan2
- OLFML2B | c.141C>T p.N47= | Silent (SNP) | VAF 77/167 reads (46%) | catalogued as rs770352048, COSV54196407; called by muse, mutect2, varscan2
- PIWIL1 | c.2112A>G p.V704= | Silent (SNP) | VAF 147/260 reads (57%) | catalogued as COSV55346765; called by muse, mutect2, varscan2
- PLA2G15 | c.372G>A p.L124= | Silent (SNP) | VAF 79/99 reads (80%) | catalogued as COSV54723162; called by muse, mutect2, varscan2
- POLA1 | c.2247C>T p.A749= | Silent (SNP) | VAF 243/927 reads (26%) | catalogued as COSV66886264; called by muse, mutect2, varscan2
- PRSS35 | c.288C>T p.T96= | Silent (SNP) | VAF 30/284 reads (11%) | called by muse, varscan2
- RBM45 | c.1284T>C p.N428= (on ENST00000616198 / NM_001365579.1; = p.N426= on NM_152945.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/178 reads (13%) | catalogued as rs935727455, COSV53720893; called by muse, mutect2, varscan2
- RHOG | c.222G>A p.Q74= | Silent (SNP) | VAF 16/135 reads (12%) | catalogued as COSV53465287; called by muse, mutect2, varscan2
- SLC12A6 | c.3048A>G p.Q1016= (on ENST00000354181 / NM_001365088.1; = p.Q965= on NM_005135.2) | Silent (SNP) | VAF 494/649 reads (76%) | catalogued as rs755892310, COSV51625989; called by muse, mutect2, varscan2
- SMG7 | c.2016C>T p.P672= | Silent (SNP) | VAF 16/21 reads (76%) | catalogued as COSV61630558; called by muse, mutect2, varscan2
- STC1 | c.303C>T p.N101= | Silent (SNP) | VAF 114/183 reads (62%) | catalogued as rs1027603215, COSV51688436; called by muse, mutect2, varscan2
- TTLL2 | c.1428G>C p.V476= | Silent (SNP) | VAF 101/541 reads (19%) | catalogued as rs768472898, COSV53443871; called by muse, mutect2, varscan2
- C3P1 | n.3123T>A | RNA (SNP) | VAF 18/487 reads (4%) | called by muse, mutect2
